Somatic mutation profile of tumor specimen TARGET-10-PASFXA-04A (aliquot TARGET-10-PASFXA-04A-01D) from TARGET case TARGET-10-PASFXA, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.5 years (2,374 days).
Specimen TARGET-10-PASFXA-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27a66cdc-58bc-46da-bd9c-24fd5531cc04.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASFXA-10A (Blood Derived Normal), aliquot TARGET-10-PASFXA-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5592fbe-6bcb-4ad7-9107-10ff6e7fe728

The open-access MAF lists 294 somatic variants for this specimen: 210 protein-altering or splice-affecting, 70 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 157, Silent 70, Frame Shift Ins 33, Nonsense Mutation 13, 5'UTR 7, Intron 5, Splice Region 3, Frame Shift Del 2, Splice Site 2, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NOD2 | c.1759C>T p.R587C | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs104895479, CM055112, COSV56054683; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 114/141 reads (81%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A1BG | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.078); catalogued as rs372209543; called by mutect2, varscan2
- ABCF3 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs773424973, COSV53050112; called by muse, mutect2, varscan2
- ACR | c.532T>C p.W178R | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as COSV53361900; called by muse, mutect2, varscan2
- ADAMTS18 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs891093965, COSV51399337; called by muse, mutect2, varscan2
- ADD2 | c.1593G>A p.P531= | Splice Region (SNP) | VAF 37/102 reads (36%) | catalogued as COSV52470394; called by muse, mutect2, varscan2
- AMIGO1 | c.1438G>T p.E480* | Nonsense Mutation (SNP) | VAF 7/105 reads (7%) | catalogued as COSV63990445; called by muse, mutect2
- ANO10 | c.1963G>A p.G655R | Missense Mutation (SNP) | VAF 78/197 reads (40%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs775593449, COSV52736053; called by muse, mutect2, varscan2
- AP000812.4 | c.653C>G p.P218R | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.651); catalogued as COSV56193623; called by muse, mutect2
- ARHGAP20 | c.1459T>C p.Y487H | Missense Mutation (SNP) | VAF 47/221 reads (21%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.886); catalogued as COSV52818787; called by muse, mutect2, varscan2
- ARHGAP32 | c.630G>A p.S210= | Splice Region (SNP) | VAF 15/124 reads (12%) | catalogued as rs749443850, COSV59843388; called by muse, mutect2, varscan2
- ARHGEF5 | c.607A>T p.T203S | Missense Mutation (SNP) | VAF 17/260 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as COSV50209253, COSV50218579; called by muse, mutect2
- ASPM | c.1457A>G p.Q486R | Missense Mutation (SNP) | VAF 28/304 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as COSV54138148; called by muse, mutect2, varscan2
- ASZ1 | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 89/232 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0.288); catalogued as COSV52916255; called by muse, mutect2, varscan2
- BDKRB1 | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759925605, COSV53707181; called by muse, mutect2, varscan2
- BLM | c.4103C>A p.S1368Y | Missense Mutation (SNP) | VAF 15/227 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV61927238; called by muse, mutect2
- BMP6 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.053); catalogued as rs201278326, COSV51672077; called by muse, mutect2, varscan2
- BRD1 | c.2440T>C p.S814P (on ENST00000216267 / NM_001349940.1; = p.S945P on NM_001304808.3) | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.249); catalogued as rs953805860, COSV53461314; called by muse, mutect2, varscan2
- C1orf112 | c.1835T>A p.L612* | Nonsense Mutation (SNP) | VAF 31/318 reads (10%) | catalogued as rs1307765347, COSV53682549; called by muse, mutect2, varscan2
- CCDC124 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs769006893, COSV71490575; called by muse, mutect2, varscan2
- CCDC171 | c.3037A>G p.K1013E | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as COSV52652404; called by muse, mutect2, varscan2
- CDK5R1 | c.673G>A p.V225I | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV55579870; called by muse, mutect2, varscan2
- CDKL5 | c.2519G>A p.R840H | Missense Mutation (SNP) | VAF 135/527 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.926); catalogued as rs1230243414, COSV66110156; called by muse, mutect2, varscan2
- CENPC | c.1496G>A p.R499H | Missense Mutation (SNP) | VAF 32/456 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs184128058, COSV56623512; called by muse, mutect2
- CEP290 | c.2423A>G p.Y808C | Missense Mutation (SNP) | VAF 67/124 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as rs773007151, COSV58355955; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CFAP46 | c.6010G>A p.A2004T | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.039); catalogued as rs895727540; called by muse, mutect2, varscan2
- CFAP58 | c.2492G>A p.R831H | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.526); catalogued as rs143080879; called by muse, mutect2, varscan2
- CFAP74 | c.917A>G p.D306G | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1047435814, COSV54573485; called by muse, mutect2, varscan2
- CHST10 | c.301T>C p.S101P | Missense Mutation (SNP) | VAF 79/314 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV51807576; called by muse, mutect2, varscan2
- CLPB | c.1808G>A p.R603H | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.964); catalogued as rs765245566, COSV53633384; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNNM3 | c.1067G>A p.R356H | Missense Mutation (SNP) | VAF 51/189 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as COSV59709949; called by muse, mutect2, varscan2
- CNOT3 | c.374G>A p.G125D | Missense Mutation (SNP) | VAF 57/221 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.575); catalogued as COSV55368195; called by muse, mutect2, varscan2
- COPS2 | c.1295A>T p.N432I | Missense Mutation (SNP) | VAF 125/503 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV54647398; called by muse, mutect2, varscan2
- CPAMD8 | c.850C>T p.R284W (on ENST00000651564; = p.R237W on NM_015692.5) | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as rs762012472, COSV52236808; called by muse, mutect2, varscan2
- CPLANE1 | c.8578G>A p.G2860R | Missense Mutation (SNP) | VAF 53/395 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.494); catalogued as rs764611797, COSV57054227; called by muse, mutect2, varscan2
- CSMD1 | c.10687A>G p.T3563A (on ENST00000520002; = p.T3562A on NM_033225.6) | Missense Mutation (SNP) | VAF 51/539 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59379511; called by muse, mutect2
- CUEDC2 | c.816G>T p.K272N | Missense Mutation (SNP) | VAF 17/323 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50059928; called by muse, mutect2
- DAZAP1 | c.770del p.P257Rfs*78 | Frame Shift Del (DEL) | VAF 11/96 reads (11%) | catalogued as COSV99245498; called by mutect2, pindel, varscan2
- DCP2 | c.668A>G p.N223S | Missense Mutation (SNP) | VAF 179/382 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.755); catalogued as COSV101203883, COSV66618249; called by muse, mutect2, varscan2
- DCST2 | c.1503A>G p.I501M | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.708); catalogued as rs757138608, COSV55054402; called by muse, mutect2, varscan2
- DNAJC7 | c.908T>C p.V303A | Missense Mutation (SNP) | VAF 160/382 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.075); catalogued as COSV57270273; called by muse, mutect2, varscan2
- DNALI1 | c.375G>T p.Q125H (on ENST00000296218; = p.Q103H on NM_003462.5) | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as COSV56171416; called by muse, mutect2, varscan2
- DNHD1 | c.2935C>T p.R979C | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as rs566226547, COSV54433194; called by muse, mutect2, varscan2
- DPF2 | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 45/166 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs770311911, COSV52891267; called by muse, mutect2, varscan2
- DUSP11 | c.77T>C p.I26T | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs781491313, COSV55596221; called by muse, mutect2, varscan2
- ECPAS | c.5101G>A p.A1701T | Missense Mutation (SNP) | VAF 14/472 reads (3%) | SIFT tolerated (0.51); PolyPhen benign (0.017); catalogued as rs898654958; called by muse, mutect2
- ENHO | c.47A>G p.N16S | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV99647060; called by muse, mutect2, varscan2
- ENOSF1 | c.1304T>C p.I435T (on ENST00000340116 / NM_001354066.2; = p.I401T on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.668); catalogued as rs753647529, COSV51895465; called by muse, mutect2, varscan2
- ESF1 | c.2281C>T p.R761W | Missense Mutation (SNP) | VAF 95/255 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52523639, COSV99176362; called by muse, mutect2, varscan2
- ETV1 | c.106A>G p.N36D | Missense Mutation (SNP) | VAF 66/333 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54151009; called by muse, varscan2
- EVPL | c.2222G>A p.R741Q | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as COSV100044206, COSV56915462; called by muse, mutect2, varscan2
- FAM186A | c.676G>T p.D226Y | Missense Mutation (SNP) | VAF 52/259 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV59254690; called by muse, mutect2, varscan2
- FBN1 | c.6188C>T p.A2063V | Missense Mutation (SNP) | VAF 28/246 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs1566896395, COSV57323753; called by muse, mutect2, varscan2
- FBXO31 | c.460G>A p.G154R | Missense Mutation (SNP) | VAF 21/189 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV61150546; called by muse, mutect2, varscan2
- FGGY | c.1127C>T p.A376V | Missense Mutation (SNP) | VAF 173/476 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.027); catalogued as COSV58045031; called by muse, mutect2, varscan2
- FHOD1 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.538); catalogued as rs1413971720, COSV50758956; called by muse, mutect2, varscan2
- FKBP15 | c.1968G>C p.Q656H | Missense Mutation (SNP) | VAF 76/281 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV53039212; called by muse, mutect2, varscan2
- FKBP8 | c.733G>A p.D245N (on ENST00000222308 / NM_001308373.2; = p.D246N on NM_012181.5) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.05); catalogued as rs1287886403; called by muse, mutect2
- FOXA1 | c.137C>T p.T46I | Missense Mutation (SNP) | VAF 70/648 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.377); catalogued as COSV51649818; called by muse, mutect2, varscan2
- FREM1 | c.4766A>T p.D1589V | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66529848; called by muse, mutect2, varscan2
- FREM2 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 5/130 reads (4%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as rs1418181141; called by muse, mutect2
- GMIP | c.1748A>G p.Q583R | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52559764; called by muse, mutect2, varscan2
- GPR180 | c.442A>G p.M148V | Missense Mutation (SNP) | VAF 29/254 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs562461734, COSV65386203; called by muse, mutect2, varscan2
- GPRC5C | c.485C>T p.A162V (on ENST00000652232; = p.A117V on NM_018653.4) | Missense Mutation (SNP) | VAF 97/245 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.598); catalogued as COSV61238720; called by muse, mutect2, varscan2
- HAVCR2 | c.616G>A p.G206R | Missense Mutation (SNP) | VAF 30/234 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as rs1266553489, COSV57152055; called by muse, mutect2, varscan2
- HK2 | c.1049G>A p.R350Q | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs571011343, COSV51879258; called by muse, mutect2, varscan2
- HRNR | c.1151C>T p.A384V | Missense Mutation (SNP) | VAF 58/169 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV64259416; called by muse, mutect2, varscan2
- IFNLR1 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as rs1193002719, COSV59527563; called by muse, mutect2, varscan2
- IGHV3-43 | c.262A>T p.T88S | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.725); catalogued as rs1158350868; called by muse, mutect2, varscan2
- INCENP | c.1913G>A p.R638H (on ENST00000394818 / NM_001040694.2; = p.R634H on NM_020238.3) | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as rs140505440; called by muse, mutect2, varscan2
- INTU | c.1268G>A p.C423Y | Missense Mutation (SNP) | VAF 88/386 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.808); catalogued as COSV58874484; called by muse, mutect2, varscan2
- KCNH7 | c.1910C>T p.T637M | Missense Mutation (SNP) | VAF 16/386 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59790598; called by muse, mutect2
- KIAA1549 | c.4427dup p.E1477Gfs*3 | Frame Shift Ins (INS) | VAF 15/72 reads (21%) | catalogued as rs752867430; called by mutect2, pindel, varscan2
- KLF11 | c.353C>T p.S118L | Missense Mutation (SNP) | VAF 72/252 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs748350805, COSV59940930; called by muse, varscan2
- KLHDC10 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 28/274 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.543); catalogued as rs149721697; called by muse, mutect2, varscan2
- LAMA5 | c.3020T>C p.L1007P | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53371729; called by muse, mutect2
- LNPK | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 74/191 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.297); catalogued as COSV55826285; called by muse, mutect2, varscan2
- LOXHD1 | c.3505G>T p.E1169* | Nonsense Mutation (SNP) | VAF 12/184 reads (7%) | catalogued as COSV56072625; called by muse, mutect2
- MACC1 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs202049959; called by muse, mutect2, varscan2
- MAP3K11 | c.952G>A p.G318R | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100482176; called by muse, mutect2
- MARCHF6 | c.2108G>A p.R703H | Missense Mutation (SNP) | VAF 74/631 reads (12%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.642); catalogued as rs772135999, COSV56878469, COSV56886776; called by muse, mutect2, varscan2
- MEGF10 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 46/428 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs778835131, COSV57245863; called by muse, mutect2, varscan2
- MLKL | c.263T>C p.F88S | Missense Mutation (SNP) | VAF 18/388 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV58206512; called by muse, mutect2
- MRPL55 | c.163_164insG p.L55Rfs*33 | Frame Shift Ins (INS) | VAF 6/41 reads (15%) | catalogued as COSV54343621; called by mutect2, varscan2
- MTCL1 | c.1339G>A p.A447T (on ENST00000306329 / NM_001378206.1; = p.A87T on NM_015210.4) | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs778152688, COSV60409766; called by muse, mutect2, varscan2
- MYH11 | c.1282A>T p.T428S | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.035); catalogued as COSV55568371; called by muse, mutect2, varscan2
- MYO15A | c.886G>A p.G296S | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as rs755830662, COSV52765417, COSV99233375; called by muse, mutect2, varscan2
- MYO18A | c.3206G>A p.S1069N | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.078); catalogued as COSV62872861; called by muse, mutect2, varscan2
- MYO18A | c.1822A>G p.T608A | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV62872874; called by muse, mutect2, varscan2
- MYO9B | c.5737C>T p.R1913* | Nonsense Mutation (SNP) | VAF 10/236 reads (4%) | catalogued as COSV101261508; called by muse, mutect2
- NBAS | c.5107A>G p.T1703A | Missense Mutation (SNP) | VAF 25/209 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as COSV55736992; called by muse, mutect2, varscan2
- NRXN1 | c.2792dup p.Q932Pfs*14 | Frame Shift Ins (INS) | VAF 28/182 reads (15%) | catalogued as rs1388095672; called by mutect2, varscan2
- NSL1 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 109/473 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs373943564; called by muse, mutect2, varscan2
- NT5C1B | c.260G>A p.C87Y | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.691); catalogued as COSV58398871; called by muse, mutect2, varscan2
- NUP153 | c.2521G>T p.G841C | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.654); catalogued as COSV50464000; called by muse, mutect2
- NUP210 | c.4441G>T p.E1481* | Nonsense Mutation (SNP) | VAF 9/35 reads (26%) | catalogued as COSV54413542; called by muse, mutect2, varscan2
- OLAH | c.489del p.K164Sfs*10 (on ENST00000378228 / NM_001039702.3; = p.K217Sfs*10 on NM_018324.3) | Frame Shift Del (DEL) | VAF 16/168 reads (10%) | catalogued as rs774581354; called by mutect2, varscan2
- OR10AD1 | c.616G>A p.V206M | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.375); catalogued as rs370150637, COSV59613099; called by muse, mutect2, varscan2
- OR52B2 | c.962T>C p.L321P | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs773410789, COSV73209573; called by muse, mutect2, varscan2
- OR5M11 | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 74/161 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs773176884, COSV73142004; called by muse, mutect2, varscan2
- OSBPL6 | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 12/302 reads (4%) | catalogued as COSV51918205; called by muse, mutect2
- OTOGL | c.2860C>T p.R954* (on ENST00000547103; = p.R945* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 30/372 reads (8%) | catalogued as rs572666403, COSV72006450; called by muse, mutect2
- PARP8 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 24/458 reads (5%) | SIFT tolerated (1); PolyPhen probably damaging (0.972); catalogued as rs1402472164, COSV55859591; called by muse, mutect2
- PCDH18 | c.1405C>T p.R469* | Nonsense Mutation (SNP) | VAF 32/174 reads (18%) | catalogued as COSV61271900; called by mutect2, varscan2
- PDS5A | c.1550G>A p.R517H | Missense Mutation (SNP) | VAF 26/224 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.799); catalogued as rs781741452, COSV57830953; called by muse, mutect2
- PHACTR4 | c.296G>A p.S99N (on ENST00000373839 / NM_001350159.2; = p.S109N on NM_023923.4) | Missense Mutation (SNP) | VAF 48/183 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV65785067; called by muse, mutect2, varscan2
- PHTF1 | c.1736T>A p.I579K | Missense Mutation (SNP) | VAF 13/183 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV63368787; called by muse, mutect2
- PLA2R1 | c.1861C>T p.R621* | Nonsense Mutation (SNP) | VAF 6/72 reads (8%) | catalogued as rs986365099; called by muse, mutect2
- PLCB2 | c.620T>C p.V207A | Missense Mutation (SNP) | VAF 105/296 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.05); catalogued as COSV53037724; called by muse, mutect2, varscan2
- PLOD3 | c.876dup p.Q293Afs*48 | Frame Shift Ins (INS) | VAF 26/74 reads (35%) | catalogued as rs746342377; called by mutect2, varscan2
- POLA1 | c.4243+2T>C p.X1415_splice | Splice Site (SNP) | VAF 40/332 reads (12%) | catalogued as COSV66890527; called by muse, varscan2
- POLD1 | c.3157C>T p.R1053C | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs779208942, COSV54532548; ClinVar: uncertain significance; called by muse, mutect2
- PTCD3 | c.1259T>C p.M420T | Missense Mutation (SNP) | VAF 51/440 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54483366; called by muse, mutect2, varscan2
- RAB5C | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60526422; called by muse, mutect2, varscan2
- RB1CC1 | c.380A>G p.E127G | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.172); catalogued as COSV50273069; called by muse, mutect2, varscan2
- RHOT2 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760549413, COSV53474056; called by muse, mutect2, varscan2
- RPGRIP1 | c.2441G>A p.R814Q | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as rs372647080, CM112006, COSV52850960, COSV52851682; called by muse, mutect2, varscan2
- RYR1 | c.7724G>A p.R2575H | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.814); catalogued as rs369450781, COSV100614940; called by muse, mutect2, varscan2
- SENP2 | c.1732A>G p.K578E | Missense Mutation (SNP) | VAF 103/237 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56197741; called by muse, mutect2, varscan2
- SETD9 | c.155T>C p.V52A | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.76); catalogued as COSV53651186; called by muse, mutect2, varscan2
- SLC15A5 | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 64/124 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1268546146, COSV61365228; called by muse, varscan2
- SLC28A3 | c.1675G>A p.A559T | Missense Mutation (SNP) | VAF 23/649 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1029476248, COSV66155031; called by muse, mutect2
- SLC9A2 | c.1778T>C p.V593A | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV52137584; called by muse, mutect2, varscan2
- SPATA17 | c.794C>A p.A265E | Missense Mutation (SNP) | VAF 109/269 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as COSV65125981; called by muse, mutect2, varscan2
- SPTBN5 | c.275G>T p.R92L | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); catalogued as COSV58024910, COSV58027648; called by muse, mutect2, varscan2
- SQLE | c.1564C>T p.H522Y | Missense Mutation (SNP) | VAF 118/280 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56282534; called by mutect2, varscan2
- ST14 | c.1468G>A p.A490T | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.099); catalogued as rs767558579, COSV53833042; called by muse, mutect2, varscan2
- ST6GALNAC2 | c.628T>C p.S210P | Missense Mutation (SNP) | VAF 34/152 reads (22%) | PolyPhen benign (0.17); catalogued as COSV56572594; called by muse, mutect2, varscan2
- STK10 | c.2017C>T p.R673* | Nonsense Mutation (SNP) | VAF 105/408 reads (26%) | catalogued as rs774125608, COSV51578643; called by muse, mutect2, varscan2
- SWT1 | c.1529A>G p.D510G | Missense Mutation (SNP) | VAF 70/157 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62258845; called by muse, mutect2, varscan2
- SYT13 | c.607A>G p.T203A | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV50076914; called by muse, mutect2, varscan2
- TAF3 | c.1309T>C p.S437P | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV60211363; called by muse, varscan2
- TAF3 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs749491126, COSV60210729; called by muse, varscan2
- TCHH | c.2218C>T p.R740W | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.853); catalogued as rs753437615, COSV64275203; called by muse, varscan2
- TIAL1 | c.44A>G p.N15S | Missense Mutation (SNP) | VAF 18/199 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV64843523; called by muse, mutect2
- TMEM184C | c.1240G>T p.A414S | Missense Mutation (SNP) | VAF 51/155 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV56854720; called by muse, mutect2, varscan2
- TMX2 | c.413T>G p.I138S | Missense Mutation (SNP) | VAF 197/639 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53556227; called by muse, mutect2, varscan2
- TNFSF12 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as rs758038102, COSV53434011; called by muse, mutect2, varscan2
- TNKS2 | c.389A>C p.E130A | Missense Mutation (SNP) | VAF 62/157 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65416907; called by muse, mutect2, varscan2
- TREM1 | c.268T>C p.Y90H | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.494); catalogued as COSV55149569; called by muse, mutect2
- TRIO | c.3233G>A p.R1078Q | Missense Mutation (SNP) | VAF 10/234 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV100710228, COSV60083986; called by muse, mutect2
- TROAP | c.352A>C p.I118L | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.099); catalogued as COSV57745874; called by muse, mutect2, varscan2
- TSPAN4 | c.591G>A p.W197* | Nonsense Mutation (SNP) | VAF 26/95 reads (27%) | catalogued as COSV60260554; called by muse, mutect2, varscan2
- TSPYL6 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.272); catalogued as rs762227245, COSV57819936; called by muse, mutect2, varscan2
- TTC39C | c.1652T>C p.L551P (on ENST00000317571 / NM_001135993.2; = p.L490P on NM_153211.4) | Missense Mutation (SNP) | VAF 112/330 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.646); catalogued as COSV58220978; called by muse, varscan2
- TTC7A | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 75/269 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs767380906, COSV55411678; called by muse, mutect2, varscan2
- TTN | c.65513G>A p.R21838Q (on ENST00000591111; = p.R14414Q on NM_003319.4) | Missense Mutation (SNP) | VAF 31/262 reads (12%) | PolyPhen possibly damaging (0.786); catalogued as rs140127488, COSV60128822, COSV60158704; called by muse, mutect2, varscan2
- UNC13B | c.4684C>G p.L1562V | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as rs1208495918, COSV61470385; called by muse, mutect2, varscan2
- UQCC1 | c.478C>T p.R160* | Nonsense Mutation (SNP) | VAF 34/384 reads (9%) | catalogued as rs1399329434, COSV62903540; called by muse, mutect2
- VWA5B1 | c.1135C>T p.R379* | Nonsense Mutation (SNP) | VAF 14/83 reads (17%) | catalogued as rs1419042903, COSV57051386, COSV57055876; called by muse, mutect2, varscan2
- YIF1A | c.526C>A p.L176M | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV61013042; called by muse, mutect2, varscan2
- ZAN | c.5324C>A p.T1775N | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.392); catalogued as COSV61815869; called by muse, mutect2, varscan2
- ZBTB39 | c.311A>G p.E104G | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55630790; called by muse, mutect2, varscan2
- ZBTB46 | c.1342T>C p.C448R | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55514621; called by muse, mutect2, varscan2
- ZC3H7A | c.379T>C p.Y127H | Missense Mutation (SNP) | VAF 75/181 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63271308; called by muse, mutect2, varscan2
- ZKSCAN4 | c.587G>C p.G196A | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (0.93); PolyPhen benign (0.018); catalogued as COSV66023965; called by muse, mutect2, varscan2
- ZNF451 | c.652T>C p.Y218H | Missense Mutation (SNP) | VAF 46/324 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.417); catalogued as COSV62599893; called by muse, mutect2, varscan2
- ZNF521 | c.2057A>T p.H686L | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64131630; called by muse, mutect2, varscan2
- ZNF572 | c.1375C>T p.R459W | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs373321198; called by muse, mutect2, varscan2
- ZNF609 | c.4228A>G p.R1410G | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV58589704; called by muse, varscan2
- ZNF618 | c.1844A>G p.Y615C (on ENST00000374126 / NM_001318042.2; = p.Y522C on NM_133374.2) | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55929021; called by muse, mutect2, varscan2
- ZNF862 | c.3365C>T p.A1122V | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV56225991; called by muse, mutect2, varscan2
- ACACA | c.1754dup p.L586Tfs*3 | Frame Shift Ins (INS) | VAF 61/356 reads (17%) | called by mutect2, pindel, varscan2
- ADAD2 | c.712G>A p.A238T (on ENST00000315906 / NM_001145400.2; = p.A310T on NM_139174.4) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADAMTSL2 | c.1661A>T p.K554M | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.818); called by muse, mutect2
- BRF1 | c.939dup p.L314Tfs*5 | Frame Shift Ins (INS) | VAF 110/310 reads (35%) | called by mutect2, varscan2
- CACNA1G | c.5325dup p.C1776Lfs*2 | Frame Shift Ins (INS) | VAF 41/132 reads (31%) | called by mutect2, pindel, varscan2
- CCDC17 | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.029); called by muse, mutect2
- CENPV | c.530dup p.Q178Afs*3 | Frame Shift Ins (INS) | VAF 40/138 reads (29%) | called by mutect2, pindel, varscan2
- CHGA | c.677dup p.R227Efs*12 | Frame Shift Ins (INS) | VAF 5/43 reads (12%) | called by mutect2, pindel
- DLGAP3 | c.294dup p.F99Lfs*5 | Frame Shift Ins (INS) | VAF 8/26 reads (31%) | called by mutect2, varscan2
- DPY19L3 | c.57dup p.P20Sfs*12 | Frame Shift Ins (INS) | VAF 68/269 reads (25%) | called by mutect2, pindel, varscan2
- DUS2 | c.1417dup p.D473Gfs*14 | Frame Shift Ins (INS) | VAF 11/81 reads (14%) | called by mutect2, pindel, varscan2
- FAM135B | c.3797G>C p.W1266S | Missense Mutation (SNP) | VAF 11/278 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FCGBP | c.2219dup p.N740Kfs*13 | Frame Shift Ins (INS) | VAF 8/43 reads (19%) | called by mutect2, pindel, varscan2
- GPR32 | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 18/513 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HECTD4 | c.8429A>G p.Y2810C | Missense Mutation (SNP) | VAF 12/163 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- IGSF8 | c.700T>C p.Y234H | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- LAMA2 | c.935A>G p.N312S | Missense Mutation (SNP) | VAF 12/316 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MYOM2 | c.2618dup p.V874Gfs*3 | Frame Shift Ins (INS) | VAF 27/51 reads (53%) | called by mutect2, pindel, varscan2
- NIPBL | c.8326dup p.I2776Nfs*7 | Frame Shift Ins (INS) | VAF 42/102 reads (41%) | called by mutect2, varscan2
- NPNT | c.716dup p.C240Vfs*4 | Frame Shift Ins (INS) | VAF 109/364 reads (30%) | called by mutect2, pindel, varscan2
- OBSL1 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, varscan2
- OR2L3 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.391); called by muse, mutect2
- PAK1 | c.1452dup p.Q485Sfs*29 | Frame Shift Ins (INS) | VAF 94/320 reads (29%) | called by mutect2, pindel, varscan2
- PAX9 | c.761dup p.Y255Vfs*62 | Frame Shift Ins (INS) | VAF 6/21 reads (29%) | called by mutect2, varscan2
- PET100 | c.138+1G>A p.X46_splice | Splice Site (SNP) | VAF 18/211 reads (9%) | called by muse, mutect2
- PHF14 | c.1742G>A p.R581Q | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.651); called by muse, mutect2
- PRKCQ | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 9/281 reads (3%) | SIFT tolerated (0.25); PolyPhen benign (0.01); called by muse, mutect2
- SETX | c.4716dup p.A1573Sfs*4 | Frame Shift Ins (INS) | VAF 12/118 reads (10%) | called by mutect2, pindel
- SH3GLB2 | c.736C>T p.H246Y | Missense Mutation (SNP) | VAF 9/317 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- SLC24A5 | c.783dup p.S262Ifs*4 | Frame Shift Ins (INS) | VAF 35/141 reads (25%) | called by mutect2, pindel, varscan2
- SLC44A2 | c.1200dup p.C401Lfs*18 | Frame Shift Ins (INS) | VAF 27/227 reads (12%) | called by mutect2, pindel, varscan2
- SLC9A1 | c.2098dup p.R700Pfs*10 | Frame Shift Ins (INS) | VAF 35/93 reads (38%) | called by mutect2, pindel, varscan2
- SPATC1 | c.1166dup p.P390Tfs*12 | Frame Shift Ins (INS) | VAF 5/22 reads (23%) | called by mutect2, varscan2
- SPG11 | c.5966dup p.N1989Kfs*11 | Frame Shift Ins (INS) | VAF 25/239 reads (10%) | called by mutect2, pindel, varscan2
- STEAP4 | c.836dup p.D281Rfs*4 | Frame Shift Ins (INS) | VAF 24/91 reads (26%) | called by mutect2, pindel, varscan2
- TBX18 | c.698A>G p.E233G | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- TFAP2A | c.705dup p.V236Sfs*26 (on ENST00000482890; = p.V228Sfs*26 on NM_001032280.3) | Frame Shift Ins (INS) | VAF 19/60 reads (32%) | called by mutect2, pindel
- TIMM10B | c.39+4A>G | Splice Region (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
- TRIM24 | c.506dup p.N169Kfs*13 | Frame Shift Ins (INS) | VAF 23/218 reads (11%) | called by mutect2, pindel, varscan2
- TSHZ3 | c.1557dup p.L520Afs*2 | Frame Shift Ins (INS) | VAF 26/158 reads (16%) | called by mutect2, varscan2
- UBAC1 | c.339dup p.Q114Tfs*8 | Frame Shift Ins (INS) | VAF 54/530 reads (10%) | called by mutect2, pindel, varscan2
- USP20 | c.1247G>T p.R416M | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); called by muse, mutect2
- USP6 | c.3095dup p.N1032Kfs*12 | Frame Shift Ins (INS) | VAF 18/98 reads (18%) | called by mutect2, varscan2
- VCAN | c.9683dup p.N3229Qfs*2 | Frame Shift Ins (INS) | VAF 129/589 reads (22%) | called by mutect2, pindel, varscan2
- WAC | c.1648dup p.R550Pfs*16 | Frame Shift Ins (INS) | VAF 42/200 reads (21%) | called by mutect2, pindel, varscan2
- ZNF562 | c.944C>T p.P315L (on ENST00000453372 / NM_001130032.2; = p.P243L on NM_017656.4) | Missense Mutation (SNP) | VAF 137/341 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF609 | c.4227dup p.R1410Qfs*48 | Frame Shift Ins (INS) | VAF 18/106 reads (17%) | called by pindel, varscan2
- AHNAK2 | c.6873A>G p.P2291= | Silent (SNP) | VAF 20/162 reads (12%) | catalogued as rs759531556, COSV60929420; called by mutect2, varscan2
- AMOT | c.1590A>G p.S530= (on ENST00000371959 / NM_001113490.1; = p.S121= on NM_133265.3) | Silent (SNP) | VAF 32/607 reads (5%) | catalogued as COSV59062579; called by muse, mutect2
- ARHGEF16 | c.744C>T p.D248= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as rs376771674; called by muse, mutect2, varscan2
- ARSK | c.810A>G p.K270= | Silent (SNP) | VAF 12/308 reads (4%) | called by muse, mutect2
- ASB4 | c.309T>C p.C103= | Silent (SNP) | VAF 61/273 reads (22%) | catalogued as COSV57508941; called by muse, mutect2, varscan2
- C7 | c.873C>T p.A291= | Silent (SNP) | VAF 38/265 reads (14%) | called by muse, mutect2, varscan2
- CCDC136 | c.1389G>A p.T463= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs769344664, COSV52804601; called by muse, mutect2, varscan2
- CDC42BPG | c.369C>T p.L123= | Silent (SNP) | VAF 74/174 reads (43%) | catalogued as rs147914897; called by muse, mutect2, varscan2
- CDK6 | c.945G>T p.P315= | Silent (SNP) | VAF 150/328 reads (46%) | catalogued as COSV56012983; called by muse, mutect2, varscan2
- CEP112 | c.2019G>A p.T673= | Silent (SNP) | VAF 194/481 reads (40%) | catalogued as rs1186027290, COSV67136499; called by muse, mutect2, varscan2
- CEPT1 | c.48G>A p.P16= | Silent (SNP) | VAF 19/166 reads (11%) | catalogued as rs775896574, COSV64110686, COSV64111563; called by muse, mutect2, varscan2
- CNTN2 | c.2184C>T p.I728= | Silent (SNP) | VAF 16/139 reads (12%) | catalogued as COSV59348572; called by muse, mutect2, varscan2
- CPA5 | c.27G>A p.T9= | Silent (SNP) | VAF 28/95 reads (29%) | catalogued as rs782186925, COSV62569692; called by muse, mutect2
- CREB1 | c.21C>T p.A7= | Silent (SNP) | VAF 49/116 reads (42%) | catalogued as rs1323012635, COSV100783522, COSV62065216, COSV62066741; called by muse, mutect2, varscan2
- CREBBP | c.3723C>T p.F1241= | Silent (SNP) | VAF 47/445 reads (11%) | catalogued as COSV52139808; called by muse, mutect2, varscan2
- DDHD1 | c.1923G>A p.S641= (on ENST00000323669; = p.S838= on NM_030637.3) | Silent (SNP) | VAF 78/260 reads (30%) | catalogued as rs756324099, COSV60362550; called by muse, mutect2, varscan2
- DENND4C | c.1536G>A p.P512= | Silent (SNP) | VAF 30/134 reads (22%) | catalogued as rs750254569, COSV100991561, COSV66823265; called by muse, varscan2
- DKK3 | c.915C>T p.P305= | Silent (SNP) | VAF 20/141 reads (14%) | catalogued as rs746442871, COSV58870408; called by muse, mutect2, varscan2
- EPHB2 | c.2682G>A p.A894= (on ENST00000400191 / NM_001309193.2; = p.A895= on NM_004442.7) | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs541814998, COSV65865898; called by mutect2, varscan2
- EZH2 | c.1581G>A p.R527= (on ENST00000460911 / NM_001203247.2; = p.R532= on NM_004456.5) | Silent (SNP) | VAF 48/200 reads (24%) | catalogued as COSV57462169; called by muse, mutect2, varscan2
- EZHIP | c.240C>T p.T80= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs902739217, COSV57955539; called by muse, mutect2, varscan2
- FAM186A | c.1926A>G p.S642= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV59254677; called by muse, mutect2, varscan2
- FLRT1 | c.1305C>T p.G435= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs762156219, COSV55367088; called by muse, mutect2
- GBP6 | c.978C>T p.A326= | Silent (SNP) | VAF 69/141 reads (49%) | catalogued as rs755564316, COSV65012567; called by muse, mutect2, varscan2
- GLB1L2 | c.1374A>G p.V458= | Silent (SNP) | VAF 58/211 reads (27%) | catalogued as rs973764002, COSV60280509; called by muse, mutect2, varscan2
- GPR156 | c.21C>T p.C7= | Silent (SNP) | VAF 93/128 reads (73%) | catalogued as COSV59942335; called by muse, mutect2, varscan2
- GPR173 | c.811C>A p.R271= | Silent (SNP) | VAF 12/132 reads (9%) | catalogued as COSV60238174; called by muse, mutect2
- IGKV2-24 | c.348T>C p.A116= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as rs532474654; called by mutect2, varscan2
- ITGB2 | c.1245G>A p.T415= (on ENST00000302347; = p.T391= on NM_000211.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 84/304 reads (28%) | catalogued as rs747895476, COSV56610283; called by muse, mutect2, varscan2
- KCNC1 | c.1230G>A p.T410= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs1295549018, COSV56395300; called by muse, mutect2, varscan2
- KDM2B | c.3177T>C p.D1059= | Silent (SNP) | VAF 14/25 reads (56%) | catalogued as COSV65644918; called by muse, mutect2, varscan2
- KMT2D | c.8448A>G p.Q2816= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as COSV56483659; called by muse, mutect2, varscan2
- KMT5A | c.924A>G p.K308= | Silent (SNP) | VAF 12/79 reads (15%) | called by muse, mutect2, varscan2
- KNTC1 | c.3375A>G p.G1125= | Silent (SNP) | VAF 14/260 reads (5%) | catalogued as COSV61083843; called by muse, mutect2
- KRT23 | c.270T>C p.V90= | Silent (SNP) | VAF 23/155 reads (15%) | catalogued as COSV52928932; called by muse, mutect2, varscan2
- KRTAP1-1 | c.444C>T p.H148= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs200919206, COSV60399069; called by muse, mutect2
- LAT | c.462C>T p.D154= | Silent (SNP) | VAF 17/123 reads (14%) | catalogued as rs535156699, COSV57956659; called by muse, mutect2, varscan2
- LIG3 | c.1332G>A p.S444= | Silent (SNP) | VAF 20/160 reads (13%) | catalogued as rs111958156; called by muse, mutect2, varscan2
- LONRF3 | c.765C>T p.R255= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as COSV59149915; called by muse, mutect2, varscan2
- LRP1 | c.11121C>T p.R3707= | Silent (SNP) | VAF 69/148 reads (47%) | catalogued as rs1456535635, COSV54525081; called by muse, mutect2, varscan2
- LRP2BP | c.789T>C p.V263= | Silent (SNP) | VAF 24/188 reads (13%) | catalogued as COSV60750889; called by muse, varscan2
- MSH3 | c.3201T>C p.S1067= | Silent (SNP) | VAF 119/488 reads (24%) | catalogued as COSV54163528; called by muse, mutect2, varscan2
- NAV1 | c.1026G>A p.T342= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as rs1187537747, COSV99818518, COSV99818528; called by muse, mutect2
- NFATC2IP | c.666G>A p.V222= | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as rs1450052232, COSV57911324; called by muse, mutect2, varscan2
- NNT | c.201A>G p.Q67= | Silent (SNP) | VAF 36/414 reads (9%) | catalogued as COSV52929399; called by muse, mutect2
- NOD1 | c.636A>G p.L212= | Silent (SNP) | VAF 43/62 reads (69%) | catalogued as COSV56114680; called by muse, mutect2, varscan2
- PADI3 | c.1803G>A p.K601= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as COSV64935354; called by muse, mutect2, varscan2
- PDHA2 | c.516C>T p.G172= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as rs372852988; called by muse, mutect2, varscan2
- PHEX | c.744C>T p.A248= | Silent (SNP) | VAF 59/581 reads (10%) | catalogued as COSV65075618; called by muse, mutect2, varscan2
- PPIP5K2 | c.1248A>T p.G416= | Silent (SNP) | VAF 60/559 reads (11%) | catalogued as COSV58609574; called by muse, mutect2, varscan2
- PRKAG2 | c.252G>A p.R84= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV55240596; called by muse, mutect2, varscan2
- RALB | c.66C>T p.S22= | Silent (SNP) | VAF 10/91 reads (11%) | catalogued as rs751629582, COSV55604873; called by muse, mutect2, varscan2
- RGS11 | c.708G>A p.A236= (on ENST00000397770 / NM_183337.3; = p.A215= on NM_003834.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/196 reads (10%) | catalogued as rs944418493, COSV51451613, COSV51452682, COSV99395600; called by muse, mutect2, varscan2
- RNF19B | c.1833G>A p.S611= | Silent (SNP) | VAF 34/148 reads (23%) | catalogued as rs752078296, COSV52389953; called by mutect2, varscan2
- SCAPER | c.957T>C p.D319= | Silent (SNP) | VAF 24/244 reads (10%) | catalogued as COSV57753383; called by muse, mutect2, varscan2
- SI | c.2883A>G p.V961= | Silent (SNP) | VAF 19/101 reads (19%) | called by muse, mutect2, varscan2
- SLC19A1 | c.1609C>T p.L537= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as COSV60593411; called by muse, mutect2, varscan2
- SLC30A2 | c.405C>T p.C135= | Silent (SNP) | VAF 19/192 reads (10%) | catalogued as rs958815166, COSV65332343; called by muse, mutect2, varscan2
- SLC39A5 | c.339T>C p.G113= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV57193534; called by muse, mutect2, varscan2
- SLC6A20 | c.1530T>C p.A510= | Silent (SNP) | VAF 43/63 reads (68%) | catalogued as COSV62072639; called by muse, mutect2, varscan2
- SLC9A2 | c.528G>A p.G176= | Silent (SNP) | VAF 61/553 reads (11%) | catalogued as COSV52137567; called by muse, mutect2, varscan2
- TGFBR3 | c.1299A>G p.Q433= | Silent (SNP) | VAF 32/263 reads (12%) | catalogued as rs1323887925, COSV53030966; called by muse, mutect2, varscan2
- TIFA | c.483G>A p.P161= | Silent (SNP) | VAF 108/376 reads (29%) | catalogued as rs373610356; called by muse, mutect2, varscan2
- TLCD3A | c.612C>T p.G204= | Silent (SNP) | VAF 118/206 reads (57%) | catalogued as COSV56747466; called by muse, mutect2, varscan2
- TMEM132C | c.1248C>T p.A416= | Silent (SNP) | VAF 23/127 reads (18%) | catalogued as rs900002247, COSV59432890; called by muse, mutect2, varscan2
- TMEM232 | c.813T>C p.A271= | Silent (SNP) | VAF 10/260 reads (4%) | called by muse, mutect2
- TTC28 | c.4797G>A p.P1599= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs1418151682, COSV67417198; called by muse, mutect2, varscan2
- VPS13B | c.366G>A p.P122= | Silent (SNP) | VAF 18/134 reads (13%) | catalogued as rs373340298; ClinVar: likely benign; called by muse, mutect2, varscan2
- VSIG4 | c.1131C>T p.Y377= | Silent (SNP) | VAF 34/243 reads (14%) | catalogued as rs200220547, COSV66074567; called by muse, mutect2, varscan2
- ZNF407 | c.3165G>A p.A1055= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as rs763527840, COSV55269071; called by muse, mutect2, varscan2
- BBS7 | c.-2T>G | 5'UTR (SNP) | VAF 51/130 reads (39%) | catalogued as COSV52659342; called by muse, mutect2, varscan2
- CPNE5 | c.1432-15dup | Intron (INS) | VAF 11/79 reads (14%) | called by mutect2, pindel, varscan2
- DMD | c.-19G>T | 5'UTR (SNP) | VAF 311/782 reads (40%) | catalogued as COSV55899343; called by muse, mutect2, varscan2
- FOLH1B | n.1603T>C | RNA (SNP) | VAF 32/387 reads (8%) | called by muse, mutect2, varscan2
- GYPE | c.-25dup | 5'UTR (INS) | VAF 50/269 reads (19%) | called by mutect2, varscan2
- MAL | c.*5G>A | 3'UTR (SNP) | VAF 35/227 reads (15%) | catalogued as rs757617050, COSV59432640; called by muse, mutect2, varscan2
- PARP11 | c.-36T>G | 5'UTR (SNP) | VAF 16/54 reads (30%) | catalogued as COSV57397497; called by muse, mutect2, varscan2
- PCDH11X | c.3144+24859C>T | Intron (SNP) | VAF 31/287 reads (11%) | catalogued as rs1289223544, COSV53501592; called by muse, mutect2, varscan2
- PLAA | c.1486+551G>A | Intron (SNP) | VAF 10/158 reads (6%) | called by muse, mutect2
- PRKAG3 | c.-8C>T | 5'UTR (SNP) | VAF 22/60 reads (37%) | catalogued as rs368183537; called by muse, varscan2
- RTKN | c.111+2070C>A | Intron (SNP) | VAF 10/127 reads (8%) | catalogued as rs1183206780, COSV51966063; called by muse, mutect2
- SATL1 | c.-163T>C | 5'UTR (SNP) | VAF 8/198 reads (4%) | called by muse, mutect2
- ZFR | c.1979+710G>A | Intron (SNP) | VAF 19/60 reads (32%) | catalogued as rs942844072; called by muse, mutect2, varscan2
- ZNF185 | c.-24G>A | 5'UTR (SNP) | VAF 23/276 reads (8%) | catalogued as COSV59278050; called by muse, mutect2
